Gene-level copy-number profile of tumor specimen ALCH-B3GR-TTP1-A from ALCHEMIST case ALCH-B3GR, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 59.2 years (21,635 days).
Specimen ALCH-B3GR-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file e0666a5b-85bd-4601-ae35-a6e088de1dd9.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B3GR-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,231 have no estimate.
https://portal.gdc.cancer.gov/files/bde0b73b-7f41-4e57-9dbd-a6e03cc23b53

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 60; copy number 1: 20,393; copy number 2: 26,089; copy number 3: 9,686; copy number 4: 1,192; copy number 5: 672; copy number 6: 294; copy number 7: 5; copy number 11: 1.

Homozygous deletions (total copy number 0; autosomes only): 60 genes in 19 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:13,892,792–15,118,043, 1 gene (within-gene range 0–2): KAZN.
- chr1:14,692,129–14,777,727, 2 genes (within-gene range 0–2): TBCAP2, AL031293.1.
- chr1:43,991,359–44,031,467, 2 genes (within-gene range 0–2): CCDC24, SLC6A9.
- chr4:1,009,936–1,028,972, 2 genes: FGFRL1, AC019103.1.
- chr4:159,665,833–159,777,828, 1 gene: LINC02233.
- chr6:37,819,727–39,229,475, 22 genes (within-gene range 0–1): ZFAND3, RN7SL285P, RNVU1-33, AL589655.1, BTBD9, AL033518.1, BTBD9-AS1, Y_RNA, AL079341.1, GLO1, AL391415.1, DNAH8, RN7SL465P, AL035555.2, AL035555.1, DNAH8-AS1, AL034345.1, AL035690.1, GLP1R, SAYSD1, ANKRD18EP, KCNK5.
- chr6:50,514,035–50,521,104, 1 gene: AL360175.1.
- chr6:98,834,574–98,839,458, 1 gene: POU3F2.
- chr8:3,373,353–3,375,226, 1 gene (within-gene range 0–2): AC026991.1.
- chr8:3,700,492–3,700,628, 1 gene (within-gene range 0–2): RNA5SP251.
- chr9:21,802,636–22,128,103, 14 genes (within-gene range 0–2): MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2.
- chr9:93,951,627–93,959,140, 2 genes: BARX1, BARX1-DT.
- chr9:136,848,724–136,860,799, 2 genes (within-gene range 0–2): PHPT1, MAMDC4.
- chr9:137,007,234–137,028,922, 1 gene (within-gene range 0–1): ABCA2.
- chr14:106,460,092–106,461,055, 1 gene (within-gene range 0–1): HOMER2P1.
- chr14:106,470,264–106,470,800, 1 gene (within-gene range 0–1): IGHV3-43.
- chr16:31,032,889–31,042,975, 1 gene: STX4.
- chr16:51,149,239–51,149,819, 1 gene (within-gene range 0–1): AC009166.1.
- chr19:19,512,418–19,536,076, 3 genes (within-gene range 0–2): TSSK6, NDUFA13, AC011448.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 970 genes in 20 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:247,416,156–247,640,854, 11 genes, copy number 5 (within-gene range 1–5): NLRP3, OR2B11, OR2W5, GCSAML, OR2C3, GCSAML-AS1, AL606804.1, OR2G2, OR2G3, U6, OR14L1P.
- chr2:52,702,522–55,952,014, 52 genes, copy number 5: MIR4431, AC010967.1, AC010967.2, AC010967.3, AC069157.2, AC069157.1, ASB3, RNU6-997P, CHAC2, ERLEC1, MIR3682, GPR75, PSME4, ACYP2, RPL21P30, HMGB1P31, AC008280.1, AC008280.2, RNU7-172P, TSPYL6, C2orf73, SPTBN1, SPTBN1-AS1, RPL23AP32, AC092839.1, AC093110.1, EML6, EML6-AS1, AC104781.1, RNU7-81P, RTN4, RNU6-433P, CLHC1, AC012358.1, CDPF1P1, RPS27A, MTIF2, PRORSD1P, AC012358.2, Y_RNA, CCDC88A, BTF3P5, RNU6-775P, RNU6-221P, RNU6-634P, CFAP36, PPP4R3B, AC015982.1, AC015982.2, PNPT1, EFEMP1, RN7SKP208.
- chr2:55,963,191–56,047,326, 4 genes, copy number 5 (within-gene range 4–5): MIR217HG, MIR217, MIR216A, MIR216B.
- chr2:60,336,446–60,802,086, 12 genes, copy number 6: MIR4432HG, AC007381.1, RNU1-32P, MIR4432, BCL11A, AC009970.1, RN7SL361P, IFITM3P9, RPL26P13, RNU6-612P, ATP1B3P1, PAPOLG.
- chr5:58,198–892,801, 32 genes, copy number 5–6 (within-gene range 4–6): AC113430.1, PLEKHG4B, Y_RNA, LRRC14B, AC021087.4, CCDC127, AC021087.3, SDHA, AC021087.5, AC021087.1, PDCD6, PDCD6-AHRR, AC021087.2, AHRR, AC010442.1, AC010442.2, EXOC3-AS1, EXOC3, PP7080, SLC9A3, SLC9A3-AS1, AC106772.2, MIR4456, AC106772.1, CEP72, TPPP, AC026740.1, ZDHHC11B, BRD9P2, ZDHHC11, SPCS2P3, BRD9.
- chr6:2,948,159–3,033,288, 7 genes, copy number 6: SERPINB6, LINC01011, NQO2, NQO2-AS1, HTATSF1P2, AL133351.4, AL133351.3.
- chr6:8,102,711–9,294,133, 7 genes, copy number 6: AL355499.1, AL355499.2, AL359378.1, SLC35B3, HULC, AL161437.1, AL137220.1.
- chr6:52,791,371–54,266,280, 46 genes, copy number 6: GSTA1, GSTA6P, GSTA5, GSTA11P, GSTA10P, GSTA3, GSTA9P, GSTA4, 7SK, RN7SK, CILK1, AL031178.1, FBXO9, AL031178.2, RN7SL244P, AL512347.1, GCM1, RNU6-464P, SOD1P1, AL512378.1, RNU1-136P, HMGB1P20, ELOVL5, MIR5685, RPS16P5, AL034374.1, RPL31P28, RPL31P33, RPA3P2, AL591034.1, RN7SKP256, NANOGP3, GCLC, AL033397.2, AL033397.1, LINC01564, KLHL31, AL590652.1, LRRC1, AL033384.2, MLIP, AL033384.1, MLIP-AS1, MLIP-IT1, ERHP2, AL359380.1.
- chr6:54,602,487–55,579,197, 10 genes, copy number 5–6: RPL10P10, RPSAP44, KRASP1, RNU6-1023P, AL512363.1, FAM83B, AL049555.1, HCRTR2, GFRAL, HMGCLL1.
- chr8:36,378,069–36,779,209, 1 gene, copy number 6 (within-gene range 3–6): AC090809.1.
- chr8:36,764,445–39,417,378, 74 genes, copy number 6 (broad region; genes not listed).
- chr8:39,522,976–43,378,510, 92 genes, copy number 6 (broad region; genes not listed).
- chr8:46,870,902–49,741,321, 52 genes, copy number 5: AC091163.3, AC091163.1, AC091163.2, MAPK6P4, RN7SKP32, AC120036.1, AC120036.5, RNU6-819P, RPL10AP2, NDUFA5P12, AC120036.3, AC120036.4, ATP6V1G1P2, AC120036.2, IGLV8OR8-1, SPIDR, AC024451.2, AC024451.4, AC024451.1, AC024451.3, RNU6-665P, CEBPD, PRKDC, Y_RNA, AC021236.1, MCM4, RNU6-519P, UBE2V2, AC104989.1, IDI1P2, RNU6-295P, RNA5SP531, RPL29P19, AC041040.1, AC026904.1, AC026904.2, AC022915.2, LINC02599, LINC02847, AC022915.1, AC022915.3, EFCAB1, AC013701.1, SNAI2, AC044893.2, PPDPFL, AC044893.1, RN7SKP294, RFPL4AP7, AC090155.2, AC090155.1, PSAT1P1.
- chr8:123,178,960–135,742,495, 196 genes, copy number 5 (broad region; genes not listed).
- chr8:139,727,725–145,066,685, 202 genes, copy number 5 (broad region; genes not listed).
- chr9:33,290,512–33,410,553, 4 genes, copy number 5: NFX1, Y_RNA, AQP7, AL356218.2.
- chr20:11,800,463–12,381,255, 8 genes, copy number 6–7: LINC00687, RN7SKP111, AL080274.1, BTBD3, AL035448.1, AL109838.1, AL136460.1, PA2G4P2.
- chr21:44,133,610–44,210,114, 1 gene, copy number 11 (within-gene range 2–11): GATD3A.
- chr22:19,121,529–21,867,680, 157 genes, copy number 5–6 (within-gene range 2–6) (broad region; genes not listed).
- chr22:22,988,263–23,008,356, 2 genes, copy number 5: AC245054.2, AC245054.1.

Autosomal genes at a single copy (total copy number 1): 18,455. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
